Somatic mutation profile of tumor specimen BA2374D (aliquot aq-BA2374D) from BEATAML1.0 case 2487, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.6 years (13,372 days).
Specimen BA2374D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f793f1b9-1aa7-4889-a79f-f8fdb1cdd937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2145D (Solid Tissue Normal), aliquot aq-BA2145D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff95c4df-0fdc-444f-aa00-3b35b742b76d

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTUD6A | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57973403; called by muse, mutect2, varscan2
- ZNF185 | c.1596C>A p.C532* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV59277156; called by muse, mutect2
- AK9 | c.117+1G>T p.X39_splice | Splice Site (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- AMIGO2 | c.1313G>T p.S438I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- MRPS35 | c.405C>T p.A135= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as rs369651864; called by muse, varscan2
- UCN | c.225G>A p.T75= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs1305676336; called by muse, mutect2, varscan2
